Somatic mutation profile of tumor specimen TCGA-A3-3383-01A (aliquot TCGA-A3-3383-01A-01D-0966-08) from TCGA case TCGA-A3-3383, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.9 years (19,324 days).
Specimen TCGA-A3-3383-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a82b188-6039-4fd6-888e-d4c390b695d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3383-11A (Solid Tissue Normal), aliquot TCGA-A3-3383-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2594c894-e3e8-4eec-836b-ae94cd4c0f91

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | hotspot (GDC flag); catalogued as rs5030818, CM941381, CM961432, COSV56542817, COSV56554019, COSV56564848; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL11A2 | c.2818G>T p.G940W (on ENST00000341947 / NM_080680.3; = p.G833W on NM_080679.2) | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554612; called by muse, mutect2, varscan2
- COL5A3 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs144021089; called by muse, mutect2, varscan2
- NEURL3 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1227121165; called by muse, mutect2, varscan2
- NUP205 | c.4465C>T p.H1489Y | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767069832; called by muse, mutect2, varscan2
- PCF11 | c.1786A>G p.R596G | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53530551, COSV53532229; called by muse, mutect2, varscan2
- SETD2 | c.3964C>T p.R1322* | Nonsense Mutation (SNP) | VAF 54/111 reads (49%) | catalogued as COSV57441467; called by muse, mutect2, varscan2
- SHROOM2 | c.4663C>T p.R1555C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66604484; called by muse, mutect2, varscan2
- SLIT2 | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 85/255 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757958276, COSV56578826; called by muse, mutect2, varscan2
- TRIM3 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs779125524; called by muse, mutect2, varscan2
- ACLY | c.2845G>A p.A949T | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CFAP251 | c.806A>T p.E269V | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- COPB2 | c.1164del p.F388Lfs*18 | Frame Shift Del (DEL) | VAF 37/139 reads (27%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.6154_6156delinsA p.C2052Tfs*23 | Frame Shift Del (DEL) | VAF 55/160 reads (34%) | called by pindel, varscan2*
- CSTF3 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CTPS1 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DOCK4 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EYA2 | c.947_949del p.A316del | In Frame Del (DEL) | VAF 41/183 reads (22%) | called by mutect2, pindel, varscan2
- FCAR | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GPR158 | c.3241A>C p.I1081L | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL1 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- GRPEL1 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 77/229 reads (34%) | called by muse, mutect2, varscan2
- ITPR2 | c.974C>G p.A325G | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR2 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYH2 | c.1266+2T>C p.X422_splice | Splice Site (SNP) | VAF 99/401 reads (25%) | called by muse, mutect2, varscan2
- NCAPH2 | c.109-2A>C p.X37_splice | Splice Site (SNP) | VAF 30/100 reads (30%) | called by muse, varscan2
- NUP133 | c.2302_2312del p.T768Wfs*12 | Frame Shift Del (DEL) | VAF 25/180 reads (14%) | called by mutect2, pindel, varscan2
- OR8G1 | c.724A>T p.S242C | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- OR8G1 | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- PBRM1 | c.329del p.N110Ifs*3 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- PITX2 | c.646T>A p.S216T (on ENST00000354925 / NM_001204397.1; = p.S223T on NM_000325.6) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- POM121C | c.1303G>C p.E435Q (on ENST00000607367; = p.E193Q on NM_001099415.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- PPM1B | c.1206T>G p.N402K | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RBM43 | c.162A>G p.I54M | Missense Mutation (SNP) | VAF 141/428 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- RHOBTB1 | c.235T>A p.S79T | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RPE65 | c.1191dup p.D398* | Frame Shift Ins (INS) | VAF 26/88 reads (30%) | called by pindel, varscan2
- TAF3 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TRIM33 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- WDR46 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR83 | c.650T>A p.L217H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZKSCAN3 | c.1561del p.S521Hfs*11 | Frame Shift Del (DEL) | VAF 37/163 reads (23%) | called by mutect2, pindel, varscan2
- ZNF600 | c.132del p.I44Mfs*17 | Frame Shift Del (DEL) | VAF 125/508 reads (25%) | called by mutect2, pindel, varscan2
- ZNF646 | c.2106dup p.E703* | Frame Shift Ins (INS) | VAF 34/115 reads (30%) | called by mutect2, pindel, varscan2
- ASCC3 | c.3453G>T p.L1151= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.861C>T p.A287= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as rs1181984333; called by muse, mutect2, varscan2
- BUB1B | c.2658G>A p.R886= | Silent (SNP) | VAF 58/187 reads (31%) | called by muse, mutect2, varscan2
- CORO7 | c.1488C>A p.T496= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs771924133; called by muse, mutect2, varscan2
- DNAJB12 | c.798G>A p.R266= (on ENST00000338820; = p.R232= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- GRID1 | c.342C>G p.L114= | Silent (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- LDLR | c.1530G>A p.T510= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as rs367655096, CD005364; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAEA | c.237C>T p.S79= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs199554247; called by muse, mutect2, varscan2
- NUP153 | c.1257A>G p.E419= | Silent (SNP) | VAF 102/317 reads (32%) | called by muse, mutect2, varscan2
- STYK1 | c.357G>A p.Q119= | Silent (SNP) | VAF 15/179 reads (8%) | called by muse, mutect2
- TMEM214 | c.174C>A p.T58= | Silent (SNP) | VAF 76/243 reads (31%) | called by muse, mutect2, varscan2
- UXS1 | c.930G>T p.V310= | Silent (SNP) | VAF 43/157 reads (27%) | called by muse, mutect2, varscan2
- AL590867.2 | n.63C>A | RNA (SNP) | VAF 34/219 reads (16%) | catalogued as rs1562375040; called by muse, mutect2, varscan2
